Somatic mutation profile of tumor specimen RC-B56Q-TTP1-A (aliquot RC-B56Q-TTP1-A-1-1-D-A93N-47) from RC case RC-B56Q, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Extranodal NK/T-cell lymphoma, nasal type; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 69.4 years (25,332 days).
Specimen RC-B56Q-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60055a5a-1e57-4834-8b96-3488ae46cd29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B56Q-NB1-B (Granulocytes; tissue type Normal), aliquot RC-B56Q-NB1-B-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3606ea6-26be-447f-87b5-28a31135a49c

The open-access MAF lists 132 somatic variants for this specimen: 91 protein-altering or splice-affecting, 30 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 30, Nonsense Mutation 6, Intron 4, 5'Flank 3, 3'Flank 2, Splice Site 1, RNA 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALT | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs111033670, CM074203, CM990631, COSV101122776; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 68/82 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACAD8 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 81/92 reads (88%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs747268139, COSV99844664; called by muse, mutect2, varscan2
- ANK3 | c.7063G>A p.E2355K | Missense Mutation (SNP) | VAF 97/185 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV55052546; called by muse, mutect2, varscan2
- ANPEP | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV55590787; called by muse, mutect2, varscan2
- BSN | c.4850G>A p.R1617Q | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs774334613; called by muse, mutect2, varscan2
- CC2D2B | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as rs1287195902; called by muse, mutect2, varscan2
- CCDC110 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs201279686, COSV56873556; called by muse, mutect2, varscan2
- CD247 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs148513413, COSV62977733; called by muse, mutect2, varscan2
- CLVS2 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs766143997, COSV104390204; called by muse, mutect2, varscan2
- CYP2C9 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867193471, COSV53249240; called by muse, mutect2, varscan2
- H3C11 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 132/286 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV58900675; called by muse, varscan2
- HCFC1 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs1557114899, COSV100129357; called by muse, mutect2, varscan2
- IGSF10 | c.4928A>G p.Y1643C | Missense Mutation (SNP) | VAF 93/195 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1419183095, COSV56792205; called by muse, mutect2, varscan2
- KMT2D | c.15475C>T p.R5159W | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99985687; called by muse, mutect2, varscan2
- LILRA1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 164/315 reads (52%) | catalogued as COSV52178676; called by muse, mutect2, varscan2
- LOXHD1 | c.5468G>A p.R1823Q (on ENST00000642948; = p.R1761Q on NM_144612.7) | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1314340409; called by muse, mutect2, varscan2
- MUC12 | c.4720G>A p.A1574T (on ENST00000379442; = p.A1431T on NM_001164462.1) | Missense Mutation (SNP) | VAF 6/569 reads (1%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as rs201941728; called by muse, mutect2
- MYCBP2 | c.4651G>A p.A1551T (on ENST00000357337; = p.A1589T on NM_015057.5) | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs1469423388; called by muse, mutect2, varscan2
- MYO15A | c.3743G>A p.R1248Q | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.333); catalogued as rs751800816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIPSNAP3B | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs754356351, COSV101044447; called by muse, mutect2, varscan2
- NTRK2 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1487008553; called by muse, mutect2, varscan2
- OR10AG1 | c.56T>G p.F19C | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56631876; called by muse, mutect2, varscan2
- OR2M4 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as rs761848850, COSV60707174; called by muse, mutect2, varscan2
- OR5B12 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV100222604; called by muse, mutect2
- OR5M8 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100510535; called by muse, mutect2, varscan2
- PRAM1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 107/233 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs749889447; called by muse, mutect2, varscan2
- RIC8B | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1206237670; called by muse, mutect2, varscan2
- RYR3 | c.6769G>A p.D2257N | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs750171875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3A | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as rs954515927, COSV54865341, COSV54882389; called by muse, mutect2, varscan2
- SHCBP1L | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 88/179 reads (49%) | catalogued as COSV99055783; called by muse, mutect2, varscan2
- SLC4A7 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs1380040877; called by muse, mutect2, varscan2
- SLC7A2 | c.1393C>T p.Q465* (on ENST00000494857 / NM_001370338.1; = p.Q504* on NM_003046.6) | Nonsense Mutation (SNP) | VAF 13/133 reads (10%) | catalogued as rs1439189685; called by muse, mutect2, varscan2
- SPEF2 | c.4864G>A p.D1622N | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100289198, COSV57432506; called by muse, mutect2, varscan2
- TTC29 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1013590458; called by muse, mutect2, varscan2
- UGP2 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99709018; called by muse, mutect2, varscan2
- XDH | c.3652G>A p.G1218R | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65146753; called by muse, mutect2
- ZBTB48 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs771166449, COSV66553322; called by muse, mutect2, varscan2
- ZRANB2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs764184838, COSV54674399; called by muse, mutect2, varscan2
- ARHGEF17 | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- B3GAT2 | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- CACNA1I | c.3646G>T p.V1216L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPJ | c.482A>T p.K161M | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CLPB | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CRYBA2 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCDC2 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSEL | c.1371C>A p.D457E | Missense Mutation (SNP) | VAF 110/222 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EPHB1 | c.2878G>T p.G960C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM120C | c.2371C>T p.L791F | Missense Mutation (SNP) | VAF 82/95 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA5 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRD | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- GALNT7 | c.1740G>A p.M580I | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- GLUD1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1739T>C p.V580A | Missense Mutation (SNP) | VAF 95/439 reads (22%) | SIFT tolerated, low confidence (0.49); called by muse, mutect2, varscan2
- HSPBAP1 | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- HYDIN | c.5461G>A p.E1821K | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- IARS2 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- KRT6C | c.1565G>C p.G522A | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRP2 | c.12392T>C p.V4131A | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MEOX2 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- METTL3 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5AC | c.16897C>T p.P5633S | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- NELFA | c.1102G>A p.E368K (on ENST00000542778; = p.E357K on NM_005663.5) | Missense Mutation (SNP) | VAF 153/311 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NELL2 | c.1654T>G p.C552G | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NHLRC3 | c.525_526insT p.D176* | Frame Shift Ins (INS) | VAF 74/115 reads (64%) | called by mutect2, pindel, varscan2
- NYNRIN | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G2 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- PALB2 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCLO | c.3919C>A p.P1307T | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PNMA6E | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 158/306 reads (52%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- POLR1F | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 89/190 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN13 | c.2876G>A p.W959* | Nonsense Mutation (SNP) | VAF 89/200 reads (45%) | called by muse, mutect2, varscan2
- ROCK1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- SH3D21 | c.640-26_651del p.X214_splice (on ENST00000453908 / NM_001162530.2; = p.X103_splice on NM_024676.5) | Splice Site (DEL) | VAF 24/88 reads (27%) | called by pindel, varscan2
- SH3D21 | c.707T>G p.F236C (on ENST00000453908 / NM_001162530.2; = p.F125C on NM_024676.5) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SHLD2 | c.184T>G p.Y62D | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SKOR2 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SLC12A1 | c.1169C>A p.A390E | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORCS1 | c.1865A>T p.K622I | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SPTA1 | c.5586A>C p.E1862D | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2
- SSTR5 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- TDO2 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 70/168 reads (42%) | called by muse, mutect2, varscan2
- TET2 | c.4597A>T p.K1533* | Nonsense Mutation (SNP) | VAF 69/165 reads (42%) | called by muse, mutect2, varscan2
- TH | c.794A>G p.E265G (on ENST00000381178 / NM_199292.3; = p.E234G on NM_000360.4) | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TNRC18 | c.8323C>T p.R2775W | Missense Mutation (SNP) | VAF 110/124 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TRANK1 | c.7188G>T p.R2396S | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- TRPC7 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- USP45 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ZBTB20 | c.425T>C p.I142T (on ENST00000474710 / NM_001164342.2; = p.I69T on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZMAT4 | c.446T>A p.L149H | Missense Mutation (SNP) | VAF 102/180 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF267 | c.919T>G p.S307A | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ABHD6 | c.330C>T p.G110= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs1175913545; called by muse, mutect2, varscan2
- ACMSD | c.471C>T p.L157= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV99298818; called by muse, mutect2, varscan2
- AHSA1 | c.396C>T p.L132= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as rs752878411, COSV53631915; called by muse, mutect2, varscan2
- ATP10A | c.1239C>T p.N413= | Silent (SNP) | VAF 70/159 reads (44%) | catalogued as rs1208414202; called by muse, mutect2, varscan2
- ATXN7L3 | c.903C>T p.N301= (on ENST00000389384 / NM_001382309.1; = p.N308= on NM_001382308.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs1162523239; called by muse, mutect2
- CCDC33 | c.1704G>A p.L568= | Silent (SNP) | VAF 74/149 reads (50%) | called by muse, mutect2, varscan2
- CELSR1 | c.6690C>T p.N2230= | Silent (SNP) | VAF 109/248 reads (44%) | catalogued as rs147425309; called by muse, mutect2, varscan2
- DCBLD1 | c.843C>T p.D281= | Silent (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- DDX51 | c.1593C>T p.D531= | Silent (SNP) | VAF 72/182 reads (40%) | catalogued as rs769510259, COSV57957601; called by muse, mutect2, varscan2
- EPPK1 | c.14040C>T p.G4680= | Silent (SNP) | VAF 85/422 reads (20%) | called by muse, mutect2, varscan2
- EREG | c.36C>T p.A12= | Silent (SNP) | VAF 75/190 reads (39%) | called by muse, mutect2, varscan2
- GRIA2 | c.1891C>T p.L631= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV52388562; called by muse, mutect2, varscan2
- H3C11 | c.96C>T p.A32= | Silent (SNP) | VAF 132/282 reads (47%) | called by muse, varscan2
- HMCN1 | c.14844T>C p.F4948= | Silent (SNP) | VAF 76/180 reads (42%) | called by muse, mutect2, varscan2
- IHH | c.120G>A p.P40= | Silent (SNP) | VAF 85/170 reads (50%) | catalogued as COSV104404016; called by muse, mutect2, varscan2
- IL10RB | c.39G>A p.L13= | Silent (SNP) | VAF 96/171 reads (56%) | catalogued as rs936692910; called by muse, mutect2, varscan2
- KDM2B | c.33G>A p.E11= | Silent (SNP) | VAF 69/137 reads (50%) | catalogued as COSV65641139; called by muse, mutect2, varscan2
- KHDRBS2 | c.159C>T p.I53= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV55496772; called by muse, mutect2
- LGR4 | c.2316C>T p.I772= | Silent (SNP) | VAF 99/191 reads (52%) | called by muse, mutect2, varscan2
- MDN1 | c.13932G>A p.Q4644= | Silent (SNP) | VAF 52/100 reads (52%) | called by muse, mutect2, varscan2
- MYO9B | c.4332C>T p.H1444= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as rs372066022; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1890G>A p.L630= | Silent (SNP) | VAF 95/178 reads (53%) | called by muse, mutect2, varscan2
- RBFA | c.150G>A p.S50= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as COSV51533154; called by muse, mutect2, varscan2
- SHC2 | c.1608C>T p.D536= | Silent (SNP) | VAF 101/234 reads (43%) | catalogued as rs1160926812, COSV52744528; called by muse, mutect2, varscan2
- TDRD1 | c.2652T>C p.I884= | Silent (SNP) | VAF 71/156 reads (46%) | called by muse, mutect2, varscan2
- TDRD9 | c.6G>T p.L2= | Silent (SNP) | VAF 46/128 reads (36%) | called by muse, mutect2, varscan2
- TOP2B | c.2265C>T p.F755= (on ENST00000264331 / NM_001330700.2; = p.F750= on NM_001068.3) | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as COSV51970697; called by muse, mutect2, varscan2
- UNC5A | c.267C>A p.I89= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as rs765661556, COSV56170903; called by muse, mutect2, varscan2
- ZNF8 | c.831G>A p.R277= | Silent (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.807G>A p.V269= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as rs1410315011; called by muse, mutect2, varscan2
- AFAP1 | c.-3+10C>T | Intron (SNP) | VAF 82/209 reads (39%) | called by muse, mutect2
- CCDC57 | c.-9+4743C>G | Intron (SNP) | VAF 72/157 reads (46%) | called by muse, mutect2, varscan2
- CTTN | c.*408G>A | 3'UTR (SNP) | VAF 89/191 reads (47%) | catalogued as rs1008264060, COSV57235905; called by muse, mutect2, varscan2
- EFEMP1 | chr2:55923913 C>T | 5'Flank (SNP) | VAF 87/213 reads (41%) | called by muse, varscan2
- ING1 | chr13:110713974 G>A | 5'Flank (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- KIF16B | c.3498+2965T>C | Intron (SNP) | VAF 87/189 reads (46%) | catalogued as rs778822427; called by muse, mutect2, varscan2
- LRRC27 | chr10:132330450 C>T | 5'Flank (SNP) | VAF 88/201 reads (44%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109866G>A | Intron (SNP) | VAF 63/151 reads (42%) | catalogued as rs766045364, COSV58441856; called by muse, mutect2, varscan2
- OR2W5 | n.1067G>A | RNA (SNP) | VAF 100/187 reads (53%) | catalogued as rs532925117; called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034618 G>A | 3'Flank (SNP) | VAF 36/103 reads (35%) | catalogued as rs923934751; called by muse, mutect2, varscan2
- ZFAND2A | chr7:1152289 C>T | 3'Flank (SNP) | VAF 42/103 reads (41%) | catalogued as rs754332604; called by muse, mutect2, varscan2
